Gene-level copy-number profile of tumor specimen TCGA-DK-AA6U-01A from TCGA case TCGA-DK-AA6U, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Age at diagnosis: 64.6 years (23,611 days).
Specimen TCGA-DK-AA6U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.2c6f703f-7559-43de-b6d0-ad110a3dd5f1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-AA6U-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c6dbc41a-4638-4df7-aadf-af6fff82222f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 736; copy number 2: 6,715; copy number 3: 14,427; copy number 4: 21,772; copy number 5: 7,487; copy number 6: 2,967; copy number 7: 1,665; copy number 8: 3,457; copy number 9: 312; copy number 10: 128; copy number 12: 17; copy number 13: 2; copy number 14: 2; copy number 15: 10; copy number 16: 5; copy number 17: 4; copy number 18: 38; copy number 19: 22; copy number 28: 12; copy number 31: 11; copy number 33: 9; copy number 40: 10; copy number 43: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-AA6U-01A-11D-A390-01): tumor purity 0.77, ploidy 2.19, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 588 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:2,319,232–2,871,231, 6 genes, copy number 18: MYT1L-AS1, AC018685.2, AC018685.3, AC011995.2, AC018685.1, AC011995.1.
- chr2:164,895,677–164,955,525, 2 genes, copy number 16: RNA5SP111, SLC38A11.
- chr2:177,212,563–177,392,697, 13 genes, copy number 9 (within-gene range 4–9): HNRNPA3, MIR4444-1, NFE2L2, DNAJC19P5, MIR3128, AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2.
- chr2:237,966,827–238,457,520, 20 genes, copy number 12–19: UBE2F, UBE2F-SCLY, RNU6-1333P, SCLY, ESPNL, KLHL30, KLHL30-AS1, ERFE, ILKAP, LINC02610, AC012485.1, HES6, PER2, AC012485.3, AC012485.2, TRAF3IP1, RNU6-234P, ASB1, AC016999.1, AC016999.2.
- chr6:20,401,879–21,602,383, 17 genes, copy number 17–40: E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr6:21,822,536–21,822,737, 1 gene, copy number 40: AL136313.1.
- chr6:37,815,777–39,322,968, 25 genes, copy number 10–33: AL121574.1, ZFAND3, RN7SL285P, RNVU1-33, AL589655.1, BTBD9, AL033518.1, BTBD9-AS1, Y_RNA, AL079341.1, GLO1, AL391415.1, DNAH8, RN7SL465P, AL035555.2, AL035555.1, DNAH8-AS1, AL034345.1, AL035690.1, GLP1R, SAYSD1, ANKRD18EP, KCNK5, KCNK17, KCNK16.
- chr6:117,907,264–119,349,761, 18 genes, copy number 10–12 (within-gene range 6–12): SLC35F1, AL450405.1, AL589993.1, CEP85L, BRD7P3, PLN, Z99496.1, SSXP10, SELENOKP3, MCM9, ASF1A, AL137009.1, FAM184A, Y_RNA, MIR548B, AL022722.2, MAN1A1, AL022722.1.
- chr11:61,615,036–62,393,412, 35 genes, copy number 10: RPLP0P2, AP002754.2, DAGLA, MYRF-AS1, MYRF, TMEM258, MIR611, FEN1, FADS2, FADS1, MIR1908, FADS3, MIR6746, RAB3IL1, RNU6-1243P, BEST1, FTH1, AP003733.3, AP003733.1, LINC02733, AP003733.2, AP002793.1, INCENP, EEF1DP8, SCGB1D1, SCGB2A1, AP003306.1, SCGB1D2, SCGB2A2, SCGB1D4, NPM1P35, AP003306.2, ASRGL1, RCC2P6, AP003064.1.
- chr19:27,638,483–31,147,981, 70 genes, copy number 13–43 (broad region; genes not listed).
- chr19:31,167,457–31,225,143, 1 gene, copy number 13: LINC01791.
- chr19:34,254,552–34,577,701, 13 genes, copy number 10: GARRE1, RPL29P33, AC010504.1, GPI, AC092073.1, PDCD2L, RN7SL154P, AC008747.1, UBA2, WTIP, RPS26P55, ZNF807P, SCGB1B2P.
- chr19:56,393,656–57,974,534, 92 genes, copy number 9 (broad region; genes not listed).
- chr20:7,633,562–13,169,103, 66 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr20:57,957,126–64,313,132, 209 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 729. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
